FM case AD2410 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/ef622b52-7818-482f-b357-5fcc85673c64

Male, 66.4 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the prostate gland; metastasis biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
